TCGA case TCGA-24-2298 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7e4e7914-ec23-4c55-98d6-3c5eecffa8e4

Demographics
Sex at birth: female; Race: white; Age at index: 55 years; Vital status: Dead; Days to death: 1,620 days (4.4 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 56.0 years (20,453 days); Year of diagnosis: 1993; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 12 days; Days to treatment end: 218 days; Number of cycles: 8; Treatment dose: 3,605 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 12 days; Days to treatment end: 218 days; Number of cycles: 8; Treatment dose: 5,830 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 474 days (1.3 years); Days to treatment end: 726 days (2.0 years); Number of cycles: 12; Treatment dose: 2,477 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 474 days (1.3 years); Number of cycles: 12; Treatment dose: 1,984 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 762 days (2.1 years); Days to treatment end: 817 days (2.2 years); Number of cycles: 2; Treatment dose: 28 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 986 days (2.7 years); Days to treatment end: 1,328 days (3.6 years); Number of cycles: 13; Treatment dose: 424 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 986 days (2.7 years); Days to treatment end: 1,328 days (3.6 years); Number of cycles: 13; Treatment dose: 731 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,454 days (4.0 years); Days to treatment end: 1,568 days (4.3 years); Number of cycles: 5; Treatment dose: 308 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 57.3 years (20,922 days); Days to diagnosis: 469 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 469 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 469 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,620 days (4.4 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2298-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-24-2298-01A-01-TS1: Section location: Top; Percent tumor cells: 74; Percent tumor nuclei: 89; Percent normal cells: 25; Percent necrosis: 1; Percent stromal cells: 0.
  Slide TCGA-24-2298-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 88; Percent normal cells: 27; Percent necrosis: 3; Percent stromal cells: 0.
- Sample TCGA-24-2298-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.2; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 8: Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy of breast carcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,620 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,620 days; disease-free interval: event (new tumor event after initially disease-free), 469 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 469 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-2298-01A-01D-0704-01): tumor purity 0.72, ploidy 2.69, whole-genome doublings 1.
